Gene-level copy-number profile of tumor specimen TARGET-10-PARMFF-09A from TARGET case TARGET-10-PARMFF, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 8.3 years (3,039 days).
Specimen TARGET-10-PARMFF-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.82c240a1-95e4-5562-9204-5d3e17b71b57.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PARMFF-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 397 have no estimate.
https://portal.gdc.cancer.gov/files/3f8fa4dc-5cd9-4492-b899-d5447f488166

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,988; copy number 1: 1,269; copy number 2: 55,878; copy number 3: 78; copy number 4: 9; copy number 20: 4.

Homozygous deletions (total copy number 0; autosomes only): 81 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:65,563,236–65,625,975, 3 genes (within-gene range 0–2): PPWD1, TRIM23, RNU6-540P.
- chr6:112,087,591–112,102,790, 1 gene (within-gene range 0–2): FAM229B.
- chr7:38,256,337–38,276,318, 5 genes: TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1.
- chr7:142,554,836–142,793,368, 37 genes: TRBV11-3, TRBV12-3, TRBV12-4, TRBV12-5, TRBV14, TRBV15, TRBV16, TRBV17, TRBV18, TRBV19, TRBV20-1, TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1.
- chr9:21,304,326–22,128,103, 35 genes: IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:32,517,353–32,589,848, 4 genes, copy number 20: HLA-DRB5, RNU1-61P, HLA-DRB6, HLA-DRB1.

Autosomal genes at a single copy (total copy number 1): 1,234. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
